Somatic mutation profile of tumor specimen TCGA-12-5295-01A (aliquot TCGA-12-5295-01A-01D-1486-08) from TCGA case TCGA-12-5295, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,161 days).
Specimen TCGA-12-5295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c7afc40-9536-4a56-b6fe-82da35e2b995.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-5295-10A (Blood Derived Normal), aliquot TCGA-12-5295-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1957b91-5a12-45d4-b9d4-b42384255d7e

The open-access MAF lists 76 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Frame Shift Del 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD1 | c.2261C>A p.A754D | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV62418024; called by muse, mutect2, varscan2
- ATAD2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.535); catalogued as COSV54885236, COSV99784402; called by muse, mutect2, varscan2
- BAHD1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs144910683, COSV69084490; called by muse, mutect2, varscan2
- BTAF1 | c.3391G>A p.G1131S | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV56437983; called by muse, mutect2, varscan2
- CCNT1 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs374831967; called by muse, mutect2, varscan2
- CEACAM16 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs772631690, COSV69188080; called by muse, mutect2, varscan2
- CFTR | c.4264C>T p.R1422W | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs373172017, CM972965; called by muse, mutect2, varscan2
- CNTNAP2 | c.1648G>C p.D550H | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62180984, COSV62182718, COSV62237984; called by muse, mutect2
- COL4A5 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1290001124, COSV60359970; called by muse, mutect2, varscan2
- COL9A1 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 98/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs773143381, COSV61833606, COSV61835935; called by muse, mutect2, varscan2
- DCC | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.686); catalogued as COSV59125705; called by muse, mutect2, varscan2
- DLC1 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 80/211 reads (38%) | catalogued as rs752937229, COSV52321405; called by muse, mutect2, varscan2
- DRD5 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58579815; called by muse, mutect2, varscan2
- FAM199X | c.1114T>C p.S372P | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.426); catalogued as COSV55434281; called by muse, mutect2, varscan2
- FKBP9 | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as rs1470596729, COSV54233675; called by muse, mutect2, varscan2
- FOXR2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV59259348; called by muse, mutect2, varscan2
- FRAS1 | c.3144A>T p.K1048N | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as COSV53636743; called by muse, mutect2, varscan2
- G3BP1 | c.1107G>T p.L369F | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV62366758; called by muse, mutect2, varscan2
- GRIA1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs766140803, COSV53598986; called by muse, varscan2
- HNRNPR | c.749T>G p.V250G | Missense Mutation (SNP) | VAF 25/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56423468; called by muse, mutect2
- ITPR2 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.08); catalogued as COSV67274582; called by muse, mutect2, varscan2
- KCNA4 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs768609099, COSV60255062; called by muse, mutect2, varscan2
- KCNT2 | c.3114G>T p.Q1038H | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV54101374; called by muse, mutect2, varscan2
- KIAA1549 | c.5089C>G p.L1697V | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54324519; called by muse, mutect2, varscan2
- KIZ | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV55687419; called by muse, mutect2, varscan2
- LRRC30 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67302150; called by muse, mutect2, varscan2
- MTUS1 | c.2527T>C p.Y843H | Missense Mutation (SNP) | VAF 117/308 reads (38%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.804); catalogued as COSV50577199; called by muse, mutect2, varscan2
- MUC16 | c.39563G>A p.G13188D | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.994); catalogued as COSV66695579; called by muse, mutect2, varscan2
- MXD1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.028); catalogued as rs757503254, COSV52480566; called by muse, mutect2, varscan2
- NECAP2 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 191/358 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61434159; called by muse, varscan2
- NMS | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.215); catalogued as rs201102943, COSV65259146; called by muse, mutect2, varscan2
- NUDT14 | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV59650726; called by muse, mutect2, varscan2
- NUDT16 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63248770; called by muse, varscan2
- OR10A6 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1265208143, COSV59164671; called by muse, mutect2, varscan2
- OR4K13 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs756620210, COSV59860515; called by muse, mutect2, varscan2
- OR51G1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV58970331; called by muse, mutect2, varscan2
- PUM1 | c.3469G>A p.G1157S | Missense Mutation (SNP) | VAF 148/303 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57089827; called by muse, mutect2, varscan2
- RASGRF1 | c.3734C>T p.T1245M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as rs987999388, COSV67250652; called by mutect2, varscan2
- RFC1 | c.2001G>T p.E667D (on ENST00000381897 / NM_001363496.2; = p.E666D on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 152/420 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62899976, COSV62900681; called by muse, mutect2, varscan2
- RYBP | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV72180913; called by muse, mutect2, varscan2
- SLC26A5 | c.833T>A p.F278Y | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV59704968; called by muse, mutect2, varscan2
- SP110 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV51269066; called by muse, mutect2, varscan2
- STAT3 | c.1922C>T p.T641I | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52884059, COSV52891925; called by muse, mutect2, varscan2
- TENM3 | c.3034G>T p.A1012S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.487); catalogued as rs771059539, COSV69315979; called by muse, mutect2, varscan2
- TMEM135 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as COSV59704957; called by muse, mutect2, varscan2
- TMEM181 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV65565364; called by muse, mutect2, varscan2
- TRIML1 | c.576G>C p.E192D | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV60196281; called by muse, mutect2, varscan2
- TTN | c.54391C>T p.P18131S (on ENST00000591111; = p.P10707S on NM_003319.4) | Missense Mutation (SNP) | VAF 91/271 reads (34%) | PolyPhen benign (0.242); catalogued as COSV60265528; called by muse, mutect2, varscan2
- VPS13A | c.8711T>C p.L2904P | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62436243; called by muse, mutect2
- YIPF6 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.199); catalogued as COSV65856161; called by muse, mutect2, varscan2
- ZFAND2B | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs749944029, COSV54699154; called by muse, mutect2, varscan2
- ZNF275 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs370916699, COSV64705191; called by muse, mutect2, varscan2
- EHBP1L1 | c.1317del p.P440Qfs*6 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- FN1 | c.1295del p.T432Mfs*12 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- UBAP1 | c.153del p.V52Yfs*39 | Frame Shift Del (DEL) | VAF 61/232 reads (26%) | called by mutect2, pindel, varscan2
- AP5B1 | c.2505C>G p.P835= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100375937, COSV100375999; called by muse, varscan2
- CCT2 | c.705T>G p.A235= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as COSV54741162; called by muse, mutect2, varscan2
- CYP2A13 | c.1195C>T p.L399= | Silent (SNP) | VAF 93/235 reads (40%) | catalogued as COSV57839569; called by muse, mutect2, varscan2
- FREM1 | c.4008C>T p.S1336= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV66528224; called by muse, mutect2, varscan2
- IQGAP3 | c.756G>A p.L252= | Silent (SNP) | VAF 130/315 reads (41%) | catalogued as COSV63253818; called by muse, varscan2
- KCNQ4 | c.990C>T p.H330= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV61274815; called by muse, mutect2, varscan2
- LEMD3 | c.1947G>A p.L649= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV57652888; called by muse, mutect2, varscan2
- LIMCH1 | c.831G>A p.T277= | Silent (SNP) | VAF 68/171 reads (40%) | catalogued as rs750254202, COSV58292871; called by muse, mutect2, varscan2
- MIDEAS | c.1650C>T p.D550= | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as rs371285703; called by muse, mutect2, varscan2
- MUC5AC | c.14511G>A p.T4837= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs562561931, COSV64368839; called by muse, mutect2
- OR10G9 | c.276C>G p.S92= | Silent (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2
- OR4C11 | c.932A>G p.*311= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV100155308; called by muse, mutect2, varscan2
- PPP1R11 | c.33C>A p.T11= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV54994181; called by muse, mutect2, varscan2
- SLC10A3 | c.972G>T p.L324= | Silent (SNP) | VAF 40/121 reads (33%) | catalogued as COSV54837091; called by muse, varscan2
- SLCO3A1 | c.1524C>T p.G508= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV59235309; called by muse, mutect2, varscan2
- SPSB4 | c.756G>A p.Q252= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV60149498; called by muse, mutect2, varscan2
- SSTR5 | c.561C>T p.N187= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs781048519, COSV53513231; called by muse, mutect2, varscan2
- STK17A | c.24C>T p.G8= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1412922106, COSV60048375; called by muse, mutect2, varscan2
- TEK | c.2301G>A p.L767= | Silent (SNP) | VAF 66/203 reads (33%) | catalogued as COSV66232116; called by muse, mutect2, varscan2
- TEX37 | c.399G>A p.P133= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as rs148580273, COSV57556564; called by muse, mutect2, varscan2
- MBNL1 | c.1016-698C>T | Intron (SNP) | VAF 72/187 reads (39%) | catalogued as COSV99220207; called by muse, mutect2, varscan2
